Somatic mutation profile of tumor specimen TARGET-40-PATMPU-01A (aliquot TARGET-40-PATMPU-01A-01D) from TARGET case TARGET-40-PATMPU, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.9 years (5,060 days).
Specimen TARGET-40-PATMPU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3663341-cf53-4014-91e7-d21cf8bb546f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PATMPU-10A (Blood Derived Normal), aliquot TARGET-40-PATMPU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a817a745-6ba2-4291-864d-282176bd92d4

The open-access MAF lists 66 somatic variants for this specimen: 40 protein-altering or splice-affecting, 11 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 11, Intron 5, RNA 5, Nonsense Mutation 4, Splice Region 3, 5'UTR 2, 3'UTR 2, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR7L | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 175/762 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745516422, COSV70167914; called by muse, mutect2, varscan2
- CCDC102B | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 86/220 reads (39%) | catalogued as rs1317937837; called by muse, mutect2, varscan2
- DPP10 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 91/810 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV59731927; called by muse, mutect2, varscan2
- EIF5AL1 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 247/1315 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs774241541; called by muse, mutect2, varscan2
- LRRK2 | c.416T>C p.L139S | Missense Mutation (SNP) | VAF 85/380 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100109485; called by muse, mutect2, varscan2
- MAML1 | c.421C>G p.R141G | Missense Mutation (SNP) | VAF 276/618 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as rs985779841; called by muse, varscan2
- PCF11 | c.2494C>G p.L832V | Missense Mutation (SNP) | VAF 183/783 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as rs759268836; called by muse, mutect2, varscan2
- PHLDB1 | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 326/1344 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as COSV61876554; called by muse, mutect2, varscan2
- PLXNA1 | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 196/321 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs1258547002; called by muse, mutect2, varscan2
- POLR1C | c.503-4C>T | Splice Region (SNP) | VAF 692/1431 reads (48%) | catalogued as rs950125476; called by muse, mutect2, varscan2
- PTGS1 | c.829G>T p.G277C | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.574); catalogued as COSV56293077; called by muse, mutect2
- SIGLEC10 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 306/1078 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs1338912180, COSV100218555, COSV59478756; called by muse, mutect2, varscan2
- ABCA4 | c.1483G>C p.A495P | Missense Mutation (SNP) | VAF 255/1107 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACER2 | c.457A>G p.T153A | Missense Mutation (SNP) | VAF 444/939 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANTXR2 | c.619A>G p.K207E | Missense Mutation (SNP) | VAF 163/728 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- BMP2 | c.443C>A p.A148E | Missense Mutation (SNP) | VAF 96/345 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2CD6 | c.784T>G p.S262A | Missense Mutation (SNP) | VAF 261/405 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- CDH6 | c.1550C>A p.P517H | Missense Mutation (SNP) | VAF 148/520 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CDH9 | c.2030T>A p.L677* | Nonsense Mutation (SNP) | VAF 172/409 reads (42%) | called by muse, mutect2, varscan2
- CEP43 | c.448G>C p.D150H | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CNTN1 | c.1677T>A p.N559K | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0.021); called by muse, mutect2
- CPA2 | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 85/292 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- EDEM3 | c.1360C>G p.H454D | Missense Mutation (SNP) | VAF 17/478 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- GKN1 | c.276del p.S93Pfs*27 | Frame Shift Del (DEL) | VAF 97/266 reads (36%) | called by mutect2, pindel, varscan2
- IGKV3D-11 | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 264/560 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KCND3 | c.220T>G p.F74V | Missense Mutation (SNP) | VAF 174/782 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LANCL2 | c.701C>A p.S234* | Nonsense Mutation (SNP) | VAF 126/498 reads (25%) | called by muse, mutect2, varscan2
- LOXHD1 | c.980A>C p.K327T | Missense Mutation (SNP) | VAF 144/566 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MAML1 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 134/404 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2
- MAN1C1 | c.559C>A p.Q187K | Missense Mutation (SNP) | VAF 208/1114 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MIS18BP1 | c.1150C>G p.Q384E | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- NEUROD6 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 176/527 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SMIM21 | c.94A>C p.K32Q | Missense Mutation (SNP) | VAF 128/527 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SMPD4BP | n.640T>G | Splice Region (SNP) | VAF 124/150 reads (83%) | called by muse, mutect2, varscan2
- SMPD4BP | n.641G>T | Splice Region (SNP) | VAF 120/147 reads (82%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.1726A>T p.K576* | Nonsense Mutation (SNP) | VAF 250/908 reads (28%) | called by muse, mutect2, varscan2
- SPEG | c.8756A>C p.E2919A | Missense Mutation (SNP) | VAF 237/357 reads (66%) | SIFT tolerated (0.32); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- TMEM121B | c.1225C>A p.L409M | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR46 | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 106/454 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- ZNF208 | c.2333A>T p.K778I | Missense Mutation (SNP) | VAF 102/222 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCC | c.2268A>G p.R756= | Silent (SNP) | VAF 153/332 reads (46%) | called by muse, mutect2, varscan2
- DSG1 | c.1218C>T p.D406= | Silent (SNP) | VAF 167/275 reads (61%) | catalogued as rs147377474; called by muse, mutect2, varscan2
- KIAA0319L | c.834C>G p.P278= | Silent (SNP) | VAF 98/466 reads (21%) | catalogued as rs1029618784; called by muse, mutect2, varscan2
- LAMC1 | c.3829T>C p.L1277= | Silent (SNP) | VAF 209/951 reads (22%) | called by muse, mutect2, varscan2
- MAML1 | c.1050C>G p.T350= | Silent (SNP) | VAF 126/376 reads (34%) | called by muse, mutect2
- MAML1 | c.1077C>T p.P359= | Silent (SNP) | VAF 138/410 reads (34%) | called by muse, mutect2
- PARP8 | c.912G>A p.L304= | Silent (SNP) | VAF 121/471 reads (26%) | catalogued as rs770955950; called by muse, mutect2, varscan2
- PCDHA9 | c.2295G>A p.Q765= | Silent (SNP) | VAF 538/1202 reads (45%) | catalogued as COSV65331021; called by muse, mutect2, varscan2
- RXFP3 | c.21C>A p.A7= | Silent (SNP) | VAF 165/553 reads (30%) | called by muse, mutect2, varscan2
- STYK1 | c.318G>T p.L106= | Silent (SNP) | VAF 17/371 reads (5%) | called by muse, mutect2
- UCHL5 | c.702G>A p.K234= | Silent (SNP) | VAF 77/375 reads (21%) | called by muse, mutect2, varscan2
- AKNAD1 | chr1:108857266 A>G | 5'Flank (SNP) | VAF 19/95 reads (20%) | called by muse, mutect2, varscan2
- AL512310.7 | n.588C>T | RNA (SNP) | VAF 95/782 reads (12%) | catalogued as rs1266375211; called by muse, mutect2, varscan2
- COL1A2 | c.-13C>G | 5'UTR (SNP) | VAF 150/501 reads (30%) | called by muse, mutect2, varscan2
- CSPG4P10 | n.1700C>A | RNA (SNP) | VAF 74/1895 reads (4%) | called by muse, mutect2
- DBF4P1 | n.1599G>A | RNA (SNP) | VAF 46/128 reads (36%) | catalogued as rs1217243545; called by muse, mutect2, varscan2
- FER1L6 | c.2985+12C>T | Intron (SNP) | VAF 36/414 reads (9%) | catalogued as rs1031429103, COSV101206018; called by muse, mutect2
- GVINP1 | n.2964C>A | RNA (SNP) | VAF 27/442 reads (6%) | called by muse, mutect2
- IST1 | c.480+32G>A | Intron (SNP) | VAF 71/256 reads (28%) | catalogued as rs1348444650; called by muse, mutect2, varscan2
- PCDHA9 | c.2394+124del | Intron (DEL) | VAF 102/587 reads (17%) | called by pindel, varscan2
- PPP4R1L | n.356T>C | RNA (SNP) | VAF 71/304 reads (23%) | called by muse, mutect2, varscan2
- SLC17A8 | c.*68T>C | 3'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- SLIT3 | c.2720-70A>G | Intron (SNP) | VAF 34/84 reads (40%) | called by muse, mutect2, varscan2
- TENM2 | c.503-120909C>T | Intron (SNP) | VAF 610/1341 reads (45%) | catalogued as COSV101585431; called by muse, mutect2, varscan2
- TTLL7 | c.-91C>G | 5'UTR (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2
- UBE2E2 | c.*23C>T | 3'UTR (SNP) | VAF 89/183 reads (49%) | catalogued as rs769907316, COSV59972908; called by muse, mutect2, varscan2
